Somatic mutation profile of tumor specimen ALCH-AEYV-TTP1-A (aliquot ALCH-AEYV-TTP1-A-3-0-D-A678-36) from ALCHEMIST case ALCH-AEYV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.9 years (23,348 days).
Specimen ALCH-AEYV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50a1a862-b168-4402-a600-b3430d5a62b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEYV-NB1-A (Blood Derived Normal), aliquot ALCH-AEYV-NB1-A-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/febec384-0ad5-4627-aa81-0b49f9ad60e3

The open-access MAF lists 203 somatic variants for this specimen: 139 protein-altering or splice-affecting, 44 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 44, Intron 10, Nonsense Mutation 7, Splice Site 3, RNA 3, 5'UTR 2, Splice Region 2, 3'UTR 2, 5'Flank 2, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AJM1 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.865); catalogued as rs1162401915; called by muse, mutect2, varscan2
- ANO5 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 38/570 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV100202188; called by muse, mutect2
- AP2A1 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as COSV62821276; called by muse, mutect2
- ATXN7 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV55749832; called by muse, mutect2, varscan2
- CADM1 | c.1138G>T p.V380F | Missense Mutation (SNP) | VAF 34/579 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100522041; called by muse, mutect2
- CARD11 | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV67800490; called by muse, mutect2
- CCDC33 | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV58352873; called by muse, mutect2
- CLK3 | c.1483C>T p.L495F (on ENST00000395066 / NM_001130028.1; = p.L347F on NM_003992.4) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59339982; called by muse, mutect2, varscan2
- COL22A1 | c.3150+1G>C p.X1050_splice | Splice Site (SNP) | VAF 19/206 reads (9%) | catalogued as COSV57337506; called by muse, mutect2
- DCK | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1323663947; called by muse, mutect2
- DEFB113 | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1443314405; called by muse, mutect2
- ENG | c.1426C>A p.Q476K | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs965119099, CM153582; called by muse, mutect2
- FAM78A | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.75); catalogued as rs547225337; called by muse, mutect2
- FATE1 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 14/202 reads (7%) | catalogued as COSV64848992; called by muse, mutect2
- FBLL1 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100606194, COSV57924540; called by muse, mutect2
- FLT1 | c.3240C>G p.S1080R | Missense Mutation (SNP) | VAF 35/383 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56719757; called by muse, mutect2
- IL17RC | c.2240G>T p.R747L (on ENST00000295981 / NM_153461.4; = p.R661L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.264); catalogued as rs1233855610; called by muse, mutect2
- KAT6B | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1259192079; called by muse, mutect2
- KIF4B | c.2716C>A p.Q906K | Missense Mutation (SNP) | VAF 33/429 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs374500958; called by muse, mutect2
- MFN1 | c.712C>A p.R238S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54941031; called by muse, mutect2
- MPP6 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as COSV99757198; called by muse, mutect2
- NECTIN2 | c.1444C>G p.P482A | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.058); catalogued as rs777078945; called by muse, mutect2, varscan2
- NFKBIA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 27/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53751830; called by muse, mutect2
- OBSCN | c.9712A>G p.M3238V | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1019105245; called by muse, mutect2
- OCRL | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 34/615 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs763583776, COSV100843431; called by muse, mutect2
- PCDHB15 | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99178903; called by muse, mutect2
- PEG3 | c.3283G>T p.E1095* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as COSV55648037; called by muse, mutect2
- PNPLA3 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 35/386 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as rs201295166, COSV53381169; called by muse, mutect2
- PYROXD1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 65/327 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs751600685; called by muse, mutect2, varscan2
- RLBP1 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51528807; called by muse, mutect2
- RXYLT1 | c.1034G>A p.C345Y | Missense Mutation (SNP) | VAF 25/490 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99707027; called by muse, mutect2
- SCG2 | c.1277C>G p.A426G | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.266); catalogued as rs1421279110; called by muse, mutect2
- SHTN1 | c.971A>G p.Y324C | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs758467847; called by muse, mutect2
- SLC38A7 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as rs1382748185; called by muse, mutect2, varscan2
- TBC1D30 | c.1852C>T p.R618* (on ENST00000542120; = p.R455* on NM_015279.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/425 reads (7%) | catalogued as rs1330542816, COSV57486095; called by muse, mutect2
- TET2 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 13/299 reads (4%) | catalogued as COSV54396559; called by muse, mutect2
- THSD7B | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 27/357 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1387275974; called by muse, mutect2
- TMEM39B | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1350273594; called by muse, mutect2
- TMTC4 | c.587A>G p.N196S (on ENST00000376234 / NM_001350577.2; = p.N215S on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1215764396; called by muse, mutect2, varscan2
- TTC7A | c.518-2A>G p.X173_splice | Splice Site (SNP) | VAF 13/87 reads (15%) | catalogued as rs1233340344, COSV99766490; called by muse, mutect2
- VCAM1 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54121849; called by muse, mutect2
- ZNF804A | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377410719; called by muse, mutect2, varscan2
- ZNF804B | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 26/258 reads (10%) | catalogued as COSV60842707; called by muse, mutect2
- ABHD17C | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ACTC1 | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 39/460 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- AFF2 | c.2633G>C p.C878S | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.332); called by muse, mutect2
- AFF2 | c.3244C>A p.L1082M | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.982); called by muse, mutect2
- APCS | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- APOA4 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.065); called by muse, mutect2
- ARIH1 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.027); called by muse, mutect2
- BIRC7 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C17orf78 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 31/364 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- C1D | c.205+5G>T | Splice Region (SNP) | VAF 36/355 reads (10%) | called by muse, mutect2, varscan2
- CACNA1G | c.3456C>A p.S1152R | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.194); called by muse, mutect2
- CCDC170 | c.1807T>A p.S603T | Missense Mutation (SNP) | VAF 56/642 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.216); called by muse, mutect2
- CDH17 | c.524A>T p.N175I | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.501); called by muse, mutect2
- CHD7 | c.8226C>G p.N2742K | Missense Mutation (SNP) | VAF 37/467 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- CHIA | c.53T>A p.L18H | Missense Mutation (SNP) | VAF 23/402 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHMP4C | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- CLDN17 | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- CLDN7 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CPT1C | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- CSMD2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH1 | c.12557C>G p.S4186C | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DRP2 | c.1651T>A p.F551I | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- ERICH3 | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 17/405 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2
- ETNPPL | c.27C>G p.D9E | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAT1 | c.11640G>C p.E3880D | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2
- FATE1 | c.456G>T p.E152D | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBXO42 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- FBXO47 | c.467T>G p.M156R | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2
- FLG | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 31/610 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.772); called by muse, mutect2
- FLG2 | c.545A>C p.H182P | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- FOXN2 | c.419G>T p.S140I | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2
- GABRG3 | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, mutect2
- GP1BB | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- HS6ST3 | c.959T>G p.V320G | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ILF2 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2
- LACTB2 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 21/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRP1B | c.6349A>C p.T2117P | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, mutect2
- MEN1 | c.1786A>G p.K596E | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2
- METTL4 | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 27/313 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- MRGPRX3 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- MSANTD1 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSANTD3 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- MYH2 | c.3138A>T p.Q1046H | Missense Mutation (SNP) | VAF 53/503 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYO3A | c.4559A>C p.E1520A | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.057); called by muse, mutect2
- MYPN | c.3690C>A p.C1230* | Nonsense Mutation (SNP) | VAF 47/615 reads (8%) | called by muse, mutect2
- NLRP11 | c.2615T>C p.I872T | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- NLRP12 | c.928T>C p.W310R | Missense Mutation (SNP) | VAF 25/418 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- NMBR | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 35/370 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.773); called by muse, mutect2
- NXF3 | c.1118G>T p.C373F | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR2AE1 | c.96G>T p.M32I | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- OR2AG2 | c.471A>G p.I157M | Missense Mutation (SNP) | VAF 14/375 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2
- OR4D5 | c.683A>T p.H228L | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2
- P2RX2 | c.853T>C p.F285L (on ENST00000343948 / NM_170683.4; = p.F213L on NM_012226.5) | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PBRM1 | c.2125A>T p.I709F | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- PDE1C | c.808T>A p.Y270N | Missense Mutation (SNP) | VAF 36/575 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDZD2 | c.792T>G p.F264L | Missense Mutation (SNP) | VAF 38/653 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2
- PHKA2 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 19/546 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2
- PIEZO2 | c.5176C>A p.H1726N | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- PLK4 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- PREX1 | c.4361G>T p.R1454L | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRKCB | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- PSG9 | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- PTPN5 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); called by muse, mutect2
- RAB7A | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.427); called by muse, mutect2
- RASA1 | c.2489T>G p.L830* | Nonsense Mutation (SNP) | VAF 22/297 reads (7%) | called by muse, mutect2
- RFX6 | c.1361A>T p.D454V | Missense Mutation (SNP) | VAF 30/405 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); called by muse, mutect2
- RIPK1 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPS17 | c.3+5G>T | Splice Region (SNP) | VAF 39/468 reads (8%) | called by muse, mutect2
- RTL9 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2
- SERPINA3 | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 50/434 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SERPINC1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETBP1 | c.3233C>G p.T1078R | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- SF3B3 | c.3608A>T p.E1203V | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SLC12A3 | c.1616C>A p.S539Y | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SLC12A4 | c.1833C>G p.F611L | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- SPEF2 | c.3200T>A p.F1067Y | Missense Mutation (SNP) | VAF 116/384 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SPON1 | c.23T>A p.L8Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- SRPX2 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 37/532 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.305); called by muse, mutect2
- SYNE1 | c.18532G>A p.E6178K (on ENST00000367255 / NM_182961.4; = p.E6107K on NM_033071.3) | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2
- TBXT | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2
- TCERG1L | c.1037G>T p.C346F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TDRD15 | c.2760G>T p.Q920H | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- TEX35 | c.*440-2A>T | Splice Site (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2, varscan2
- TFG | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.073); called by muse, mutect2
- TMC7 | c.1553A>T p.K518M | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- TRAP1 | c.1331A>G p.Y444C | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); called by muse, mutect2
- TRIM42 | c.974G>C p.S325T | Missense Mutation (SNP) | VAF 30/335 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.113); called by muse, mutect2
- TRPC1 | c.1045A>G p.K349E (on ENST00000476941 / NM_001251845.2; = p.K315E on NM_003304.4) | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.069); called by muse, mutect2
- TTN | c.17525G>T p.G5842V (on ENST00000591111; = p.G4915V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/792 reads (9%) | PolyPhen possibly damaging (0.663); called by muse, mutect2
- TTN | c.1970C>T p.S657F (on ENST00000591111; = p.S611F on NM_003319.4) | Missense Mutation (SNP) | VAF 40/471 reads (8%) | PolyPhen benign (0.082); called by muse, mutect2
- USP15 | c.2474G>T p.W825L (on ENST00000280377 / NM_001351159.2; = p.W796L on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/515 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WASH6P | c.1252G>T p.G418C | Missense Mutation (SNP) | VAF 30/822 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- WDR87 | c.4598C>A p.S1533Y | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ZBTB10 | c.2399G>T p.R800L (on ENST00000430430; = p.R776L on NM_023929.4) | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF112 | c.1712A>G p.H571R (on ENST00000337401 / NM_001083335.2; = p.H565R on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF526 | c.1784A>T p.H595L | Missense Mutation (SNP) | VAF 20/295 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2
- ABCG1 | c.1299C>T p.I433= | Silent (SNP) | VAF 24/376 reads (6%) | catalogued as rs754413272, COSV59203009; called by muse, mutect2
- ADGRA3 | c.1983A>G p.K661= | Silent (SNP) | VAF 20/291 reads (7%) | called by muse, mutect2
- ADO | c.321G>T p.T107= | Silent (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2, varscan2
- C1QTNF5 | c.168C>T p.D56= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as rs1218475061; called by muse, mutect2, varscan2
- CASKIN2 | c.1599G>T p.V533= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- CCDC168 | c.18819C>T p.R6273= | Silent (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- COL19A1 | c.3003C>T p.G1001= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs765948304, COSV59568298; called by muse, mutect2
- COL9A3 | c.441C>T p.P147= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs41306378, COSV100673381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMD | c.234C>T p.N78= | Silent (SNP) | VAF 45/708 reads (6%) | catalogued as rs1370357378; called by muse, mutect2
- ENPP1 | c.2559C>A p.T853= | Silent (SNP) | VAF 28/432 reads (6%) | called by muse, mutect2
- EPPK1 | c.3186G>A p.V1062= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs1554660608, COSV101599809; called by muse, mutect2
- ERICH3 | c.894G>T p.V298= | Silent (SNP) | VAF 16/348 reads (5%) | called by muse, mutect2
- FST | c.1026A>G p.L342= | Silent (SNP) | VAF 16/177 reads (9%) | called by muse, mutect2
- GDF6 | c.180G>T p.A60= | Silent (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- GPC4 | c.1629C>T p.V543= | Silent (SNP) | VAF 22/254 reads (9%) | catalogued as rs754737646; called by muse, mutect2
- H2AC17 | c.190C>T p.L64= | Silent (SNP) | VAF 19/279 reads (7%) | catalogued as rs369125137; called by muse, mutect2
- KLRD1 | c.240A>G p.K80= | Silent (SNP) | VAF 52/392 reads (13%) | catalogued as rs987491687; called by muse, mutect2, varscan2
- MEGF10 | c.267G>A p.R89= | Silent (SNP) | VAF 24/294 reads (8%) | catalogued as COSV99174659; called by muse, mutect2
- MOV10L1 | c.2862C>T p.F954= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as rs781435954, COSV53177719, COSV99435138; called by muse, mutect2, varscan2
- MRGPRX3 | c.771C>T p.S257= | Silent (SNP) | VAF 25/227 reads (11%) | catalogued as COSV101283485; called by muse, mutect2, varscan2
- MYO18A | c.1806G>C p.L602= | Silent (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- NEO1 | c.120G>A p.P40= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- NPAP1 | c.2175G>T p.L725= | Silent (SNP) | VAF 13/198 reads (7%) | catalogued as rs1451815181; called by muse, mutect2
- NTRK2 | c.72C>A p.G24= | Silent (SNP) | VAF 34/490 reads (7%) | called by muse, mutect2
- OCA2 | c.2385G>T p.G795= | Silent (SNP) | VAF 36/506 reads (7%) | catalogued as COSV62352661; called by muse, mutect2
- OR1E1 | c.564C>T p.A188= | Silent (SNP) | VAF 40/426 reads (9%) | called by muse, mutect2
- OR56B1 | c.384T>A p.A128= | Silent (SNP) | VAF 25/487 reads (5%) | called by muse, mutect2
- P2RY4 | c.940C>A p.R314= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as COSV100996997; called by muse, mutect2
- PARP8 | c.1350A>C p.A450= | Silent (SNP) | VAF 21/344 reads (6%) | called by muse, mutect2
- PLCB1 | c.891C>A p.R297= | Silent (SNP) | VAF 58/231 reads (25%) | called by muse, mutect2, varscan2
- PLXNB3 | c.4386G>T p.L1462= | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2
- PROSER3 | c.819A>T p.P273= | Silent (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- PTGER4 | c.75G>T p.A25= | Silent (SNP) | VAF 78/259 reads (30%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.582A>G p.G194= | Silent (SNP) | VAF 58/1138 reads (5%) | called by muse, mutect2
- SETD7 | c.879C>T p.H293= | Silent (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- SLC17A6 | c.1246T>C p.L416= | Silent (SNP) | VAF 20/336 reads (6%) | catalogued as COSV54134206; called by muse, mutect2
- SLC3A1 | c.1362T>A p.T454= | Silent (SNP) | VAF 39/520 reads (8%) | called by muse, mutect2
- SPI1 | c.252C>G p.L84= | Silent (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- SYTL4 | c.321G>A p.K107= | Silent (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- THOC2 | c.901C>A p.R301= | Silent (SNP) | VAF 21/321 reads (7%) | catalogued as COSV99832534; called by muse, mutect2
- TMEM121B | c.114C>A p.R38= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- TTC27 | c.2157T>C p.Y719= | Silent (SNP) | VAF 36/458 reads (8%) | catalogued as rs766060732; called by muse, mutect2
- VSTM2L | c.453G>A p.K151= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs781264256; called by muse, mutect2, varscan2
- WDR90 | c.4848G>A p.V1616= | Silent (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
- ARMCX4 | c.1038+1661C>T | Intron (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2
- ATG13 | c.790-822C>G | Intron (SNP) | VAF 20/308 reads (6%) | called by muse, mutect2
- CLEC6A | c.-7C>A | 5'UTR (SNP) | VAF 16/357 reads (4%) | called by muse, mutect2
- COX7A1 | c.102+32C>A | Intron (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- FAM220BP | n.709G>A | RNA (SNP) | VAF 28/436 reads (6%) | called by muse, mutect2
- FMN2 | c.-9G>T | 5'UTR (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- FMR1 | c.*1704G>C | 3'UTR (SNP) | VAF 36/432 reads (8%) | catalogued as COSV54422574; called by muse, mutect2
- HERC2P3 | n.1568C>G | RNA (SNP) | VAF 24/650 reads (4%) | called by muse, mutect2
- LCP1 | c.1369-331C>T | Intron (SNP) | VAF 18/252 reads (7%) | catalogued as rs755929525; called by muse, mutect2
- LIMA1 | c.120-2448G>A | Intron (SNP) | VAF 10/238 reads (4%) | catalogued as rs907430218; called by muse, mutect2
- LINC01193 | n.849G>T | RNA (SNP) | VAF 42/1112 reads (4%) | called by muse, mutect2
- LY6G6E | c.178+40C>T | Intron (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2, varscan2
- OSBPL6 | c.*180G>T | 3'UTR (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- PDE4C | c.-209-19C>T | Intron (SNP) | VAF 7/90 reads (8%) | catalogued as rs1461790080; called by muse, mutect2
- RAD9A | chr11:67391957 G>T | 5'Flank (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- RBM6 | c.2682+455G>T | Intron (SNP) | VAF 30/373 reads (8%) | called by muse, mutect2
- SLAMF8 | chr1:159841224 T>A | 3'Flank (SNP) | VAF 23/238 reads (10%) | called by muse, mutect2
- SPTA1 | c.7134+20C>A | Intron (SNP) | VAF 32/462 reads (7%) | called by muse, mutect2
- XIAP | chrX:123860184 G>A | 5'Flank (SNP) | VAF 18/408 reads (4%) | called by muse, mutect2
- ZEB2 | c.73+5241G>C | Intron (SNP) | VAF 26/478 reads (5%) | catalogued as rs1398417319; called by muse, mutect2
